Gene-level copy-number profile of tumor specimen TARGET-20-PANTWV-09A from TARGET case TARGET-20-PANTWV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.3 years (5,230 days).
Specimen TARGET-20-PANTWV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.a2a813bc-8b11-5567-a991-7e144131a498.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PANTWV-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 348 have no estimate.
https://portal.gdc.cancer.gov/files/31556f18-76fe-4e9d-8eed-0fa39c1fc1d5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 526; copy number 1: 479; copy number 2: 59,004; copy number 3: 262; copy number 4: 3; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,812,142–28,871,267, 1 gene (within-gene range 0–2): OPRD1.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr11:116,813,204–116,823,304, 3 genes: AP006216.2, AP006216.3, APOA4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:29,824,742–29,826,711, 1 gene, copy number 5: ME2P1.

Autosomal genes at a single copy (total copy number 1): 479. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
